CPTAC case C3L-03717 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/16b182b9-f1be-4973-b6dc-0407d8c88d01

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1963; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 54.3 years (19,827 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC pathologic T: T1c; AJCC pathologic N: N0; AJCC pathologic stage: Stage IA3; Tumor grade: G1; Residual disease: RX; Days to last known disease status: 167 days; Days to last follow up: 167 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.3 cm (a second GDC size field records 4 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 13; Margin status: Uninvolved.

Follow-up (1 entry)
- Days to follow up: 167 days; Karnofsky performance status: 100; ECOG performance status: 0.

Other clinical attributes
- Weight: 90.9 kg; Height: 179.5 cm; BMI: 28.21.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 45; Cigarettes per day: 30; Tobacco smoking onset year: 1976; Tobacco smoking quit year: 2006; Exposure duration years: 30.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03717-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 118 days; Initial weight: 144 mg; Time between excision and freezing: 16 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03717-21: Section location: Right Upper Lobe; Percent tumor nuclei: 60; Percent necrosis: 0.
- Sample C3L-03717-02: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 118 days; Initial weight: 80 mg; Time between excision and freezing: 17 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-03717-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 118 days; Method of sample procurement: Blood Draw.
